Surgical pathology report (de-identified scan), TCGA case TCGA-FJ-A3ZE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Baylor, specimen TCGA-FJ-A3ZE-01A (Primary Tumor).

[page 1 of 2]
DOCTOR:

DATE OF:

Pathology Consultation Report

Final

CASE:

ANATOMIC PATHOLOGY DIAGNOSIS:

Urinary bladder, TURBT

- Invasive high grade urothelial carcinoma
- Tumor invades into muscularis propria
- Extensive tumor necrosis
- Focal lymphovascular invasion by carcinoma

1CD-0-3

carcinoma, urothelial, NOS 8/20/3

Site: bladder, NOS CL7.9

hw
9/28/12

PATHOLOGIST:

I have reviewed this material and confirm the report. Released by electronic signature on

MATERIAL:

Bladder tumor.

HISTORY:

1 male with bladder cancer.

Prior Malignancy/History		☒

hw
8/27/12

GROSS:

Received in formalin, labeled "bladder tumor," are multiple pieces of irregular tan-pink to yellow rubbery tissue, aggregating to 6.0 x 5.3 x 2.4 cm. The specimen is submitted in toto in cassettes A1-16.

MICROSCOPIC:

Page 1 of 2

SURGICAL PATHOLOGY

[page 2 of 2]
DATE OF DISCHARGE:

DOCTOR:

DATE OF SERVICE.

Pathology Consultation Report

Final

CASE:

Sections show an invasive high grade urothelial carcinoma (TCC grade 3 of 3). Tumor is present throughout the specimen. There is extensive tumor necrosis. Focal lymphovascular invasion is identified (A3). Muscularis propria is present, and is multifocally involved by carcinoma.

Page 2 of 2

SURGICAL PATHOLOGY

Source: NCI Genomic Data Commons file 7fbfa5f1-8c22-4fe8-b939-91d3f39aab0d (TCGA-FJ-A3ZE.A6FF1E82-2C6B-40F5-9F5E-96562F8EE796.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).